Gene-level copy-number profile of tumor specimen TCGA-BT-A42C-01A from TCGA case TCGA-BT-A42C, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 64.6 years (23,584 days).
Specimen TCGA-BT-A42C-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.e5612aad-e707-4c87-9953-262d4928a2ab.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BT-A42C-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ea484929-3dd9-4865-8e3b-e17d51ff98e5

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 974; copy number 2: 6,305; copy number 3: 14,857; copy number 4: 16,867; copy number 5: 13,916; copy number 6: 3,564; copy number 7: 2,638; copy number 8: 164; copy number 9: 64; copy number 10: 168; copy number 11: 117; copy number 12: 7; copy number 15: 11; copy number 17: 74; copy number 26: 89.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BT-A42C-01A-11D-A23L-01): tumor purity 0.66, ploidy 3.46, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 530 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:69,985,876–73,181,724, 117 genes, copy number 11 (within-gene range 7–11) (broad region; genes not listed).
- chr12:63,760,358–63,823,895, 4 genes, copy number 12: AC084357.1, RXYLT1, RXYLT1-AS1, PABPC1P4.
- chr12:63,871,739–63,888,598, 3 genes, copy number 12: RPL36AP41, AC079866.2, AC079866.1.
- chr12:64,222,337–64,397,065, 1 gene, copy number 17 (within-gene range 2–17): AC012158.1.
- chr12:64,264,762–72,670,758, 173 genes, copy number 15–26 (within-gene range 2–26) (broad region; genes not listed).
- chr13:104,125,930–104,134,257, 1 gene, copy number 10: AL136524.1.
- chr18:47,390–11,390,729, 231 genes, copy number 9–10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 673. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
